FM case AD10752 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/4986db64-7ab1-4bd0-a906-0b22163bfbe4

Female, 55.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the ovary; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
